CCDI case PBBRLS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Larynx.
https://portal.gdc.cancer.gov/cases/85f77cff-bb22-4f09-9220-53a3f06bac3b

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Carcinoma in situ, NOS: ICD-O-3 morphology code: 8010/2; Tissue or organ of origin: Larynx, NOS; Age at diagnosis: 24.4 years (8,910 days).

Biospecimens (2 samples)
- Sample 0DIMWF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIMX8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
